MMRF case MMRF_1077 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/71d62f8d-51db-4b5b-b3d3-a364b70f70a7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.7 years (24,743 days); ISS stage: II; Days to last known disease status: 1,792 days (4.9 years); Days to last follow up: 1,792 days (4.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 32 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 31 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 205 days; Days to treatment end: 205 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 245 days; Days to treatment end: 259 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 267 days; Days to treatment end: 267 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,792.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 0): M Protein 2.48 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 100 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 29.6 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 5.35 µg/mL; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.53 ×10⁹/L; Platelets 198 ×10⁹/L; Calcium 2.15 mmol/L; Albumin 39 g/L.
- Day 71 (ECOG 0): M Protein 1.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.47 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 4.95 mmol/L.
- Day 162: M Protein 0.99 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 1.53 g/L; Immunoglobulin M 0.66 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.52 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 8.3 g/dL; Glucose 8.53 mmol/L.
- Day 252 (ECOG 0): M Protein 1.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.47 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.26 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 10.4 mmol/L.
- Day 329 (ECOG 0): Hemoglobin 7.07 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.29 mmol/L.
- Day 421 (ECOG 0): M Protein 0.72 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.69 g/L; Hemoglobin 6.63 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.55 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 7.4 g/dL; Glucose 9.24 mmol/L.
- Day 511 (ECOG 1): M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 2.9 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.15 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 11.4 mmol/L.
- Day 616 (ECOG 1): M Protein 0.92 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.52 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 0.68 µg/mL; Hemoglobin 6.82 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 20.1 mmol/L.
- Day 714 (ECOG 2): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.13 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.53 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.15 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 9.08 mmol/L.
- Day 786 (ECOG 1): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.28 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.73 g/L; Beta 2 Microglobulin 0.85 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.57 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.5 g/dL; Glucose 5.61 mmol/L.
- Day 889 (ECOG 1): M Protein 0.87 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 14.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.55 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 9.57 mmol/L.
- Day 946 (ECOG 1): M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.45 mg/dL; Immunoglobulin G 21.4 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.32 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 40 g/L; Total Protein 8 g/dL; Glucose 11.2 mmol/L.
- Day 1,085 (ECOG 1): M Protein 0.68 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.4 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 2.89 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.26 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.95 mmol/L; Albumin 35 g/L; Total Protein 7.1 g/dL; Glucose 14.4 mmol/L.
- Day 1,141: M Protein 0.83 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.92 mg/dL; Immunoglobulin G 18.7 g/L; Immunoglobulin A 2.73 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.63 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.03 mmol/L; Albumin 39 g/L; Total Protein 7.5 g/dL; Glucose 17.8 mmol/L.
- Day 1,218: M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.31 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 3.15 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.17 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 1.98 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 11.8 mmol/L.
- Day 1,344: M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 18.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.82 mg/dL; Immunoglobulin G 19.9 g/L; Immunoglobulin A 2.44 g/L; Immunoglobulin M 0.39 g/L; Hemoglobin 5.39 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.21 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2 mmol/L; Albumin 39 g/L; Total Protein 7.7 g/dL; Glucose 13.5 mmol/L.
- Day 1,428: M Protein 2.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 51.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.73 mg/dL; Immunoglobulin G 37.4 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 4.71 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 8.9 g/dL; Glucose 22.1 mmol/L.
- Day 1,512 (ECOG 1): M Protein 2.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.01 mg/dL; Immunoglobulin G 28.6 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.09 g/L; Hemoglobin 4.77 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 36 g/L; Total Protein 7.7 g/dL; Glucose 7.65 mmol/L.
- Day 1,610: M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 48.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.17 mg/dL; Immunoglobulin G 17.7 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 5.89 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 0.89 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 7.3 g/dL; Glucose 11.6 mmol/L.
- Day 1,724: M Protein 3.54 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 442 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 46 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 4.53 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.49 ×10⁹/L; Platelets 92 ×10⁹/L; Creatinine 342 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 10 g/dL; Glucose 14.5 mmol/L.
- Day 1,791: M Protein 3.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 263 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 43.5 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 4.65 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.02 ×10⁹/L; Platelets 48 ×10⁹/L; Creatinine 206 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 9.1 g/dL; Glucose 15.1 mmol/L.

Other clinical attributes
- Day -21: Weight: 110 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1077_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_1077_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
